Somatic mutation profile of tumor specimen TCGA-AC-A5EI-01A (aliquot TCGA-AC-A5EI-01A-11D-A27P-09) from TCGA case TCGA-AC-A5EI, project TCGA-BRCA (Breast Invasive Carcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Phyllodes tumor, malignant; Tissue or organ of origin: Breast, NOS; AJCC pathologic stage: Stage IB; Age at diagnosis: 88.6 years (32,375 days).
Specimen TCGA-AC-A5EI-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 2a46edbd-60fb-498f-9378-304e5302c253.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-AC-A5EI-10A (Blood Derived Normal), aliquot TCGA-AC-A5EI-10A-01D-A27P-09; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/bb58d2eb-d34b-4905-8a3e-64c63100f215

The open-access MAF lists 31 somatic variants for this specimen: 25 protein-altering or splice-affecting, 5 silent, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 20, Silent 5, Splice Site 2, In Frame Del 1, RNA 1, Frame Shift Ins 1, Frame Shift Del 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ADAM32 | c.1934C>T p.S645L | Missense Mutation (SNP) | VAF 11/49 reads (22%) | SIFT tolerated (0.67); PolyPhen benign (0.031); catalogued as rs757189886, COSV65948045; called by muse, mutect2, varscan2
- AIPL1 | c.127G>A p.D43N | Missense Mutation (SNP) | VAF 5/36 reads (14%) | SIFT tolerated (0.21); PolyPhen benign (0.06); catalogued as COSV100005994; called by muse, mutect2, varscan2
- CORIN | c.2957G>A p.G986D | Missense Mutation (SNP) | VAF 4/32 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.942); catalogued as COSV99903201; called by muse, mutect2
- CPXCR1 | c.92T>A p.I31K | Missense Mutation (SNP) | VAF 6/39 reads (15%) | SIFT tolerated (0.22); PolyPhen benign (0.033); catalogued as COSV99342063; called by muse, mutect2, varscan2
- FREM1 | c.3109G>A p.E1037K | Missense Mutation (SNP) | VAF 5/38 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV101084015; called by muse, mutect2, varscan2
- GATA3 | c.922-3_922-2del p.X308_splice | Splice Site (DEL) | VAF 8/58 reads (14%) | catalogued as rs763236375, COSV60515023; called by mutect2, pindel, varscan2
- MTRR | c.4G>A p.G2S | Missense Mutation (SNP) | VAF 9/115 reads (8%) | SIFT tolerated, low confidence (0.14); PolyPhen benign (0.005); catalogued as rs772125269, COSV99241417; called by muse, mutect2
- NEDD9 | c.2171A>G p.N724S | Missense Mutation (SNP) | VAF 27/45 reads (60%) | SIFT tolerated (0.16); PolyPhen benign (0.275); catalogued as rs754090293, COSV101060788; called by muse, mutect2, varscan2
- NOS2 | c.125A>G p.D42G | Missense Mutation (SNP) | VAF 5/27 reads (19%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.445); catalogued as COSV100569540; called by muse, mutect2, varscan2
- NRCAM | c.2359C>T p.R787C (on ENST00000379028 / NM_001371124.1; = p.R771C on NM_005010.4 and 21 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 24/60 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as rs769341831, COSV61043555; called by muse, mutect2, varscan2
- NUTM1 | c.48G>T p.M16I | Missense Mutation (SNP) | VAF 6/19 reads (32%) | SIFT deleterious (0.04); PolyPhen benign (0.085); catalogued as COSV100182275; called by muse, mutect2
- NYNRIN | c.5252C>T p.S1751F | Missense Mutation (SNP) | VAF 22/44 reads (50%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.652); catalogued as COSV101230507; called by muse, mutect2, varscan2
- OTUD7A | c.617G>A p.G206E | Missense Mutation (SNP) | VAF 6/59 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100192085; called by muse, mutect2, varscan2
- PKD1L1 | c.5625G>C p.W1875C | Missense Mutation (SNP) | VAF 50/106 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV99218951; called by muse, mutect2, varscan2
- POM121 | c.3541C>G p.P1181A (on ENST00000434423; = p.P916A on NM_172020.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 45/136 reads (33%) | SIFT tolerated (0.38); PolyPhen probably damaging (0.996); catalogued as COSV99987839; called by muse, mutect2, varscan2
- PRPF19 | c.200C>T p.S67L | Missense Mutation (SNP) | VAF 5/39 reads (13%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.862); catalogued as COSV99920498; called by muse, mutect2, varscan2
- RYR2 | c.5011C>T p.R1671W | Missense Mutation (SNP) | VAF 46/90 reads (51%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as rs747404408, COSV63657221; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- SLC6A3 | c.991G>A p.A331T | Missense Mutation (SNP) | VAF 5/70 reads (7%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.73); catalogued as COSV54369893; called by muse, mutect2
- TUBGCP6 | c.3080G>A p.G1027E | Missense Mutation (SNP) | VAF 18/60 reads (30%) | SIFT tolerated (0.24); PolyPhen benign (0.007); catalogued as COSV99955103; called by muse, mutect2, varscan2
- ZBTB20 | c.742T>A p.Y248N (on ENST00000474710 / NM_001164342.2; = p.Y175N on NM_015642.6 and 4 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 19/39 reads (49%) | SIFT deleterious, low confidence (0.04); PolyPhen probably damaging (0.987); catalogued as COSV100613140; called by muse, mutect2, varscan2
- ZNF608 | c.910G>A p.D304N | Missense Mutation (SNP) | VAF 9/60 reads (15%) | SIFT deleterious (0.01); PolyPhen benign (0.147); catalogued as COSV100101290; called by muse, mutect2, varscan2
- CBFB | c.207dup p.P70Sfs*13 | Frame Shift Ins (INS) | VAF 4/42 reads (10%) | called by pindel, varscan2
- CCDC178 | c.968_972del p.K323Rfs*3 | Frame Shift Del (DEL) | VAF 10/22 reads (45%) | called by mutect2, pindel, varscan2
- OTUD4 | c.2974_2976del p.T992del (on ENST00000447906 / NM_001366057.1; = p.T927del on NM_001102653.1) | In Frame Del (DEL) | VAF 22/45 reads (49%) | called by mutect2, pindel, varscan2
- PIK3R1 | c.1737_1745+1del p.X579_splice (on ENST00000521381 / NM_181523.3; = p.X309_splice on NM_181504.4) | Splice Site (DEL) | VAF 20/37 reads (54%) | called by mutect2, pindel, varscan2
- LRRC25 | c.534A>G p.G178= | Silent (SNP) | VAF 21/72 reads (29%) | catalogued as COSV100170469; called by muse, mutect2, varscan2
- MISP | c.1203G>A p.P401= | Silent (SNP) | VAF 23/70 reads (33%) | catalogued as rs769053768, COSV53121902; called by muse, mutect2, varscan2
- OSBPL5 | c.1869G>C p.P623= | Silent (SNP) | VAF 27/62 reads (44%) | catalogued as COSV55141330, COSV99720166; called by muse, mutect2, varscan2
- SCN1A | c.135C>T p.D45= | Silent (SNP) | VAF 21/48 reads (44%) | catalogued as rs201985242; ClinVar: conflicting interpretations of pathogenicity; called by muse, mutect2, varscan2
- TWNK | c.1623C>T p.V541= | Silent (SNP) | VAF 29/93 reads (31%) | catalogued as COSV100147003; called by muse, mutect2, varscan2
- LINC02843 | n.490T>A | RNA (SNP) | VAF 7/41 reads (17%) | catalogued as rs373966548; called by muse, mutect2, varscan2
